Somatic mutation profile of tumor specimen MMRF_2592_1_BM_CD138pos (aliquot MMRF_2592_1_BM_CD138pos_T1_KHS5U_L12845) from MMRF case MMRF_2592, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.8 years (21,839 days).
Specimen MMRF_2592_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d031fe90-faf8-4dd7-902f-d719f5e0465e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2592_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2592_1_PB_Whole_C2_KHS5U_L12846; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dfd1050-06fa-46d7-8986-8c244baa8b20

The open-access MAF lists 148 somatic variants for this specimen: 56 protein-altering or splice-affecting, 21 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 35, Intron 23, Silent 21, 5'UTR 8, Nonsense Mutation 5, Splice Region 3, 3'Flank 3, 5'Flank 2, Frame Shift Del 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC004922.1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764232067, COSV99403106; called by muse, mutect2, varscan2
- ACTN2 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as rs773297054; called by muse, mutect2, varscan2
- AFF4 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54795732; called by muse, mutect2, varscan2
- ATM | c.5833G>T p.A1945S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53786520; called by muse, mutect2, varscan2
- CHST10 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as rs149656297; called by muse, mutect2, varscan2
- CRTAC1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs200767311, COSV53996883; called by muse, mutect2, varscan2
- DCAF12L1 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV64421734, COSV64422590; called by muse, mutect2, varscan2
- F7 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs751863700; called by muse, mutect2, varscan2
- FAHD1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs372337381; called by muse, mutect2, varscan2
- FAM163A | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs772845482; called by muse, mutect2, varscan2
- FCHO1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777535869; called by muse, mutect2, varscan2
- HEATR5B | c.5146A>G p.M1716V | Missense Mutation (SNP) | VAF 108/253 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs569306285, COSV51855402; called by muse, varscan2
- IGHV2-70 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs765459987; called by muse, varscan2
- IGHV2-70 | c.256A>C p.T86P | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs757180345; called by muse, varscan2
- IGLL5 | c.70T>A p.W24R | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV73250940; called by muse, varscan2
- IGLL5 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.175); catalogued as rs566542698; called by muse, varscan2
- KIF26B | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs369063711; called by muse, mutect2, varscan2
- NPY2R | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199805893, COSV100279821, COSV61527814; called by muse, mutect2, varscan2
- NR6A1 | c.937A>G p.I313V (on ENST00000487099 / NM_033334.4; = p.I308V on NM_001489.5) | Missense Mutation (SNP) | VAF 73/96 reads (76%) | SIFT tolerated (0.73); PolyPhen benign (0.1); catalogued as rs759821120; called by muse, mutect2, varscan2
- PPIG | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434858664, COSV53641955; called by muse, mutect2, varscan2
- PPM1E | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs763113201, COSV57579515; called by muse, mutect2, varscan2
- PROSER3 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 163/257 reads (63%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV56552444; called by muse, mutect2, varscan2
- RSPO2 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 45/90 reads (50%) | catalogued as COSV52640252; called by muse, mutect2, varscan2
- RYR2 | c.5902C>A p.P1968T | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs900782673; called by muse, mutect2, varscan2
- SLITRK2 | c.839C>A p.T280N | Missense Mutation (SNP) | VAF 120/236 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs781891605, COSV59428333; called by muse, mutect2, varscan2
- TSR1 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as rs753593435, COSV100027104, COSV56787342; called by muse, mutect2, varscan2
- ZNF853 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as rs935984370, COSV71922844; called by muse, mutect2, varscan2
- ACTN1 | c.2362-7C>T | Splice Region (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- ANKFN1 | c.1607A>G p.E536G | Missense Mutation (SNP) | VAF 85/154 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CDK5R1 | c.922T>C p.*308Rext*3 | Nonstop Mutation (SNP) | VAF 67/143 reads (47%) | called by muse, mutect2, varscan2
- CWH43 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ERO1A | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- GABRA3 | c.-26-1G>T | Splice Site (SNP) | VAF 92/218 reads (42%) | called by muse, mutect2, varscan2
- GCNT1 | c.229A>T p.I77F | Missense Mutation (SNP) | VAF 113/175 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IGFBP3 | c.*15G>A | Splice Region (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- IGHG2 | c.361del p.L121Sfs*11 | Frame Shift Del (DEL) | VAF 40/95 reads (42%) | called by mutect2, pindel, varscan2
- IGHV1-69 | c.283A>T p.T95S | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- LAG3 | c.1351C>G p.L451V | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- LTBP4 | c.3118C>T p.Q1040* (on ENST00000308370 / NM_001042544.1; = p.Q1003* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 37/205 reads (18%) | called by muse, mutect2, varscan2
- LY9 | c.454+3G>T | Splice Region (SNP) | VAF 132/207 reads (64%) | called by muse, mutect2, varscan2
- MUC16 | c.27844T>A p.S9282T | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC16 | c.4295T>A p.L1432* | Nonsense Mutation (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
- MYG1 | c.490A>C p.M164L | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBAS | c.262A>C p.I88L | Missense Mutation (SNP) | VAF 71/125 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- NEDD4L | c.1387G>A p.D463N (on ENST00000400345 / NM_001144967.3; = p.D443N on NM_015277.6) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD5 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PAIP1 | c.370T>A p.L124I | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by mutect2, varscan2
- PCSK1N | c.221A>T p.E74V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PHF20L1 | c.2783A>G p.N928S | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- PIK3R1 | c.2152G>T p.V718L (on ENST00000521381 / NM_181523.3; = p.V448L on NM_181504.4) | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- RFC5 | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHBDF2 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RLIM | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TRAPPC12 | c.930G>A p.W310* | Nonsense Mutation (SNP) | VAF 102/200 reads (51%) | called by muse, mutect2, varscan2
- TRHDE | c.2678C>T p.T893I | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ZC2HC1B | c.289A>C p.M97L | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGB | c.2760T>G p.T920= | Silent (SNP) | VAF 44/69 reads (64%) | catalogued as COSV100828463; called by muse, mutect2, varscan2
- ARHGAP42 | c.2133A>T p.G711= | Silent (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5628C>T p.S1876= (on ENST00000651564; = p.S1829= on NM_015692.5) | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs907039996; called by muse, mutect2, varscan2
- DAAM1 | c.2829A>G p.E943= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs761565015; called by muse, mutect2, varscan2
- DMD | c.4719C>T p.S1573= | Silent (SNP) | VAF 86/207 reads (42%) | called by muse, mutect2, varscan2
- FAM155A | c.90C>T p.I30= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- FERMT1 | c.1494G>A p.R498= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV54091962; called by muse, mutect2, varscan2
- IGHV2-70 | c.54A>G p.L18= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs187704106; called by muse, mutect2, varscan2
- IGLV4-69 | c.246C>T p.I82= | Silent (SNP) | VAF 71/121 reads (59%) | called by muse, mutect2, varscan2
- KIF20B | c.1461C>G p.S487= | Silent (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- KIF26B | c.5679C>T p.G1893= | Silent (SNP) | VAF 76/240 reads (32%) | catalogued as rs771007934, COSV63639764; called by muse, mutect2, varscan2
- KIF2B | c.1311G>A p.R437= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV52130250; called by muse, mutect2, varscan2
- LPA | c.4701G>A p.P1567= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs750455624, COSV60312821; called by muse, mutect2, varscan2
- MYO10 | c.360G>A p.Q120= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs760052858; called by muse, mutect2, varscan2
- PHF19 | c.912C>G p.T304= | Silent (SNP) | VAF 54/155 reads (35%) | called by muse, mutect2, varscan2
- PIFO | c.423G>A p.P141= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as rs548343385; called by muse, mutect2, varscan2
- SRGAP2 | c.552G>A p.A184= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs782810768; called by mutect2, varscan2
- TGFB2 | c.366C>T p.F122= | Silent (SNP) | VAF 142/242 reads (59%) | called by muse, mutect2, varscan2
- USP5 | c.876G>A p.T292= | Silent (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- ZMYM2 | c.2067T>G p.T689= | Silent (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2
- ZNF438 | c.2004T>C p.D668= | Silent (SNP) | VAF 12/276 reads (4%) | catalogued as rs1245942388; called by muse, mutect2
- ABCD1 | c.*305C>T | 3'UTR (SNP) | VAF 25/40 reads (63%) | catalogued as rs1480907837; called by muse, mutect2, varscan2
- ABI3BP | c.1576+9162G>A | Intron (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- ADARB2 | c.*601del | 3'UTR (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel*, varscan2
- AHR | c.-174G>T | 5'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+124G>A | Intron (SNP) | VAF 13/33 reads (39%) | catalogued as COSV61448748; called by muse, mutect2, varscan2
- BTNL9 | c.929-162C>A | Intron (SNP) | VAF 157/258 reads (61%) | called by muse, varscan2
- C2orf81 | c.-245T>C | 5'UTR (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- CFLAR | c.523+304T>C | Intron (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- CHMP3 | c.*1427A>T | 3'UTR (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- CHRM3 | c.*4254T>G | 3'UTR (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- CLIC4 | chr1:24745408 T>C | 5'Flank (SNP) | VAF 4/8 reads (50%) | catalogued as COSV65527130; called by muse, mutect2, varscan2
- CPED1 | c.*1216G>A | 3'UTR (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2, varscan2
- DENND3 | c.2845-108G>A | Intron (SNP) | VAF 83/160 reads (52%) | catalogued as rs896604942; called by muse, mutect2, varscan2
- DLGAP2 | c.*4172T>A | 3'UTR (SNP) | VAF 68/151 reads (45%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*4173T>C | 3'UTR (SNP) | VAF 68/151 reads (45%) | called by muse, mutect2, varscan2
- DNM3 | c.1911+1309A>T | Intron (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- EHF | c.*438G>T | 3'UTR (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- ELOVL5 | c.*831_*833del | 3'UTR (DEL) | VAF 43/93 reads (46%) | called by mutect2, pindel, varscan2
- ESRP1 | c.*396T>A | 3'UTR (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2
- FAM117A | c.*488G>A | 3'UTR (SNP) | VAF 38/80 reads (48%) | catalogued as rs1406774909; called by muse, mutect2, varscan2
- FBXO44 | c.*1595T>G | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, varscan2
- FBXO44 | c.*1675T>C | 3'UTR (SNP) | VAF 7/20 reads (35%) | catalogued as rs1451407509; called by muse, varscan2
- FER | c.*4346C>A | 3'UTR (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- FLT1 | c.*2003G>C | 3'UTR (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- GLRA4 | c.203-73G>T | Intron (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- GPX8 | c.*121G>A | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- GREM2 | c.*3063C>T | 3'UTR (SNP) | VAF 46/132 reads (35%) | catalogued as rs868383312, COSV58954871; called by muse, mutect2, varscan2
- GRM7 | c.2451+28697G>T | Intron (SNP) | VAF 22/43 reads (51%) | catalogued as rs1009958705; called by muse, mutect2, varscan2
- IKZF3 | c.-2A>G | 5'UTR (SNP) | VAF 81/161 reads (50%) | called by muse, mutect2, varscan2
- KANK1 | c.-39C>T | 5'UTR (SNP) | VAF 74/292 reads (25%) | called by muse, mutect2, varscan2
- KANSL2 | c.973+193T>C | Intron (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- KCND1 | c.*756T>C | 3'UTR (SNP) | VAF 45/91 reads (49%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44571288 G>T | 3'Flank (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- LAPTM5 | c.-23T>C | 5'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- LEPROT | c.279+146C>T | Intron (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2
- LIAS | c.428+111T>G | Intron (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- LIAS | c.429-152T>A | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- LPIN2 | c.-9-21968A>T | Intron (SNP) | VAF 104/217 reads (48%) | called by muse, mutect2, varscan2
- LRRC7 | c.*790G>T | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- LST1 | c.135+189dup | Intron (INS) | VAF 8/24 reads (33%) | called by mutect2, pindel
- LTB | c.209-58G>C | Intron (SNP) | VAF 42/83 reads (51%) | catalogued as COSV65815493; called by muse, mutect2, varscan2
- LTB | c.163-41G>C | Intron (SNP) | VAF 139/327 reads (43%) | catalogued as rs4647183, COSV53001370; called by muse, mutect2, varscan2
- LURAP1L | c.-133C>T | 5'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as rs1366318176; called by muse, mutect2, varscan2
- MERTK | c.*456A>C | 3'UTR (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- MESP2 | c.*362C>G | 3'UTR (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- MFHAS1 | c.*660T>A | 3'UTR (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- MTR | c.*2969A>G | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- NDUFS2 | c.1116+81A>G | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as rs1324735508; called by muse, mutect2, varscan2
- NOTCH1 | c.*541C>T | 3'UTR (SNP) | VAF 83/126 reads (66%) | catalogued as rs927406613; called by muse, mutect2, varscan2
- NRG3 | chr10:82985772 G>T | 3'Flank (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- ODR4 | c.*2168A>C | 3'UTR (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- OPCML | c.*1093C>A | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- PANK2 | chr20:3926017 A>G | 3'Flank (SNP) | VAF 59/120 reads (49%) | catalogued as rs1031818026; called by muse, mutect2, varscan2
- PHACTR1 | c.1447+1406C>T | Intron (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- PHACTR1 | c.1447+1407C>T | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- PHF7 | c.*189G>A | 3'UTR (SNP) | VAF 44/82 reads (54%) | catalogued as rs932988396; called by muse, mutect2, varscan2
- PLD6 | c.*784G>A | 3'UTR (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2
- PLP2 | c.-12C>G | 5'UTR (SNP) | VAF 59/123 reads (48%) | called by muse, mutect2, varscan2
- RBP1 | c.253-6252G>A | Intron (SNP) | VAF 44/85 reads (52%) | catalogued as rs1438368721; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158863 G>A | 5'Flank (SNP) | VAF 15/34 reads (44%) | catalogued as rs981333486; called by muse, mutect2, varscan2
- SLC30A6 | c.*3583C>T | 3'UTR (SNP) | VAF 41/82 reads (50%) | catalogued as rs918197991; called by muse, mutect2, varscan2
- SNN | c.*2425A>C | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- TEDC2 | c.27-33G>A | Intron (SNP) | VAF 26/34 reads (76%) | called by muse, mutect2, varscan2
- TNFSF8 | c.*358_*395del | 3'UTR (DEL) | VAF 32/86 reads (37%) | called by mutect2, pindel
- TPO | c.*51G>A | 3'UTR (SNP) | VAF 176/418 reads (42%) | catalogued as rs369317717, COSV100222727; called by muse, mutect2
- TRAK2 | c.900+98T>A | Intron (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- UBE2I | c.*1822_*1823del | 3'UTR (DEL) | VAF 35/93 reads (38%) | called by mutect2, pindel, varscan2
- VAV3 | c.322-6019A>G | Intron (SNP) | VAF 26/54 reads (48%) | catalogued as rs370044921; called by muse, mutect2
- ZNF24 | c.*1488T>A | 3'UTR (SNP) | VAF 22/49 reads (45%) | catalogued as rs1026693633; called by muse, mutect2, varscan2
- ZNF44 | c.*169G>A | 3'UTR (SNP) | VAF 4/68 reads (6%) | catalogued as COSV61136263; called by muse, mutect2
- ZNF493 | c.-154G>A | 5'UTR (SNP) | VAF 104/320 reads (33%) | called by muse, mutect2, varscan2
